Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAOI, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAOI-01A (Primary Tumor).

[page 1 of 2]
Name:

Sex:

ICD-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
9/25/14

Operative Procedure: ORCHIECTOMY

- Specimen Source: LEFT TESTICLE AND CORD
- Gross Exam Date:
- Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA MULTIFOCAL (2.5 CM) AND (1.8 CM) , left testis, radical orchiectomy. (See note)
2. LYMPHOVASCULAR INVASION IDENTIFIED.
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR.
6. INTRATUBULAR GERM CELL NEOPLASIA.
7. pT2NXMX.
8. SEMINIFEROUS TUBULES WITH EVIDENCE OF SPERMATOGENESIS.

Note: The seminoma and the intratubular germ neoplasia are cklt positive and CAM5.2 negative confirming the diagnosis.

GROSS DESCRIPTION:

The specimen is received in one part labeled with the patient's name, and "left testicle and cord." It was received fresh and is now in formalin, and consists of a 60-grams orchiectomy specimen including 7 x 5 x 2.5-cm testicle and a 9.5 x 2.3-cm spermatic cord. The epididymis measures 2.5 x 1.2 x 1 cm. At the lower pole of the testicle, 1 cm away from the tail of the epididymis are two discrete nodules present, one of which measures 2.5 x 1.5 x 1.2 cm and the second nodule measures 1.8 x 1.6 x 1.3 cm. Sectioning shows tan-white well-circumscribed lesions which appear homogenous and fleshy, without any areas of hemorrhage or necrosis. Tunica albuginea is not grossly involved. Neither is the epididymis. The rest of the testicular parenchyma appears tan-brown and unremarkable. The spermatic cord consists of vas deferens, arteries, and veins and is unremarkable.

Sections are submitted as follows:

1. Spermatic cord resection margin.
2. Mid spermatic cord.
3. Distal spermatic cord.

IN FT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION
---	-----------------------------	------------------------

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
Name:

Operative Procedure: ORCHIECTOMY

- Specimen Source: LEFT TESTICLE AND CORD
- Gross Exam Date:
- Physician:

Pager No.:

- 4. Epididymis with adjacent testes.
- 5-6. Larger tumor nodule.
- 7-8. Smaller tumor nodule along with adjacent testicular parenchyma, R8.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION
---	-----------------------------

PATIENT IDENTIFICATION

SURGICAL PATHOLOGY TISSUE REPORT

Source: NCI Genomic Data Commons file 32a715d1-3869-4b3f-9d30-65ea46128111 (TCGA-XE-AAOI-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).